Somatic mutation profile of tumor specimen MP2PRT-PAPSTK-TMP1-A (aliquot MP2PRT-PAPSTK-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPSTK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,089 days).
Specimen MP2PRT-PAPSTK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33f2c9f1-2120-4c7e-aa7f-31c94547dc5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPSTK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPSTK-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48f669b5-d2ba-4fd9-ac55-d042b5910593

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 84/234 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDH4 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 64/364 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs147702496; called by muse, mutect2, varscan2
- COL5A3 | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1314048372, COSV99319541; called by muse, mutect2, varscan2
- LPO | c.2064C>A p.S688R | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs748123677; called by muse, varscan2
- SPON1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1554927966, COSV59969549; called by muse, mutect2, varscan2
- TTN | c.27738G>C p.L9246F (on ENST00000591111; = p.L8319F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/216 reads (33%) | PolyPhen possibly damaging (0.693); catalogued as COSV59935908; called by muse, mutect2, varscan2
- CAMK2B | c.969G>A p.P323= | Silent (SNP) | VAF 95/260 reads (37%) | catalogued as rs748787629, COSV99322934; called by muse, mutect2, varscan2
- LIPI | c.351C>T p.F117= | Silent (SNP) | VAF 70/344 reads (20%) | catalogued as rs548960957, COSV60708768; called by muse, mutect2, varscan2
